MMRF case MMRF_1965 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/aef6c82a-78a3-4c65-baca-a79a2d71caa6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.4 years (22,053 days); ISS stage: III; Days to last known disease status: 988 days (2.7 years); Days to last follow up: 988 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 6 days; Days to treatment end: 60 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone + Doxorubicin + Lenalidomide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 81 days; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 111 days; Days to treatment end: 111 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 112 days; Days to treatment end: 112 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 261 days; Days to treatment end: 264 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 262 days; Days to treatment end: 265 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 264 days; Days to treatment end: 264 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: First line of therapy; Days to treatment start: 266 days; Days to treatment end: 266 days.
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 855 days (2.3 years); Days to treatment end: 938 days (2.6 years).
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 855 days (2.3 years); Days to treatment end: 903 days (2.5 years).
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 904 days (2.5 years); Days to treatment end: 910 days (2.5 years).
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 911 days (2.5 years); Days to treatment end: 924 days (2.5 years).
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 925 days (2.5 years); Days to treatment end: 945 days (2.6 years).
   Treatment given: Therapeutic agents: Pomalidomide + Prednisone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 946 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 0): M Protein 5.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 33.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 78.7 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 5.59 µg/mL; Lactate Dehydrogenase 6.55 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 11 g/dL; Glucose 4.79 mmol/L.
- Day 81 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.552 mg/dL; Immunoglobulin G 16 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 6.1 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.96 ×10⁹/L; Platelets 290 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 7.9 g/dL; Glucose 4.62 mmol/L.
- Day 190 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 8.16 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 6.5 g/dL; Glucose 4.95 mmol/L.
- Day 282 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 7.09 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 26.3 µkat/L; Hemoglobin 4.09 mmol/L; Leukocytes 1.1 ×10⁹/L; Absolute Neutrophil 0.99 ×10⁹/L; Platelets 14 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 5.2 g/dL; Glucose 6.16 mmol/L.
- Day 363 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.428 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.241 mg/dL; Immunoglobulin G 1.95 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 17.7 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 11.6 ×10⁹/L; Absolute Neutrophil 10.5 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 5.61 mmol/L.
- Day 453 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.444 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.693 mg/dL; Immunoglobulin G 1.71 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 9.09 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 319 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.63 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 5.39 mmol/L.
- Day 558 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.814 mg/dL; Immunoglobulin G 5.42 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 320 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 5.23 mmol/L.
- Day 648 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 5.07 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 4.1 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 357 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 5.7 g/dL; Glucose 5.06 mmol/L.
- Day 740 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 6.54 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 1.11 g/L; Lactate Dehydrogenase 11.5 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 5.12 mmol/L.
- Day 831 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 20.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.51 mg/dL; Immunoglobulin G 18.6 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 1.05 g/L; Beta 2 Microglobulin 8.72 µg/mL; Lactate Dehydrogenase 9.9 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 12.8 ×10⁹/L; Absolute Neutrophil 11.4 ×10⁹/L; Platelets 452 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 7.5 g/dL; Glucose 8.91 mmol/L.
- Day 890 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 2.15 g/L; Beta 2 Microglobulin 3.14 µg/mL; Lactate Dehydrogenase 13.1 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 7.3 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 6.05 mmol/L.
- Day 988 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Immunoglobulin G 6.8 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 1.36 g/L; Lactate Dehydrogenase 12.5 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 14.9 ×10⁹/L; Absolute Neutrophil 13.1 ×10⁹/L; Platelets 395 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.68 mmol/L; Albumin 48 g/L; Total Protein 7.3 g/dL; Glucose 5.67 mmol/L.

Other clinical attributes
- Day -1: Weight: 55 kg; Height: 152 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (3 samples)
- Sample MMRF_1965_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_1965_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
- Sample MMRF_1965_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
